Somatic mutation profile of tumor specimen C3N-04382-02 (aliquot CPT0240670006) from CPTAC case C3N-04382, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 47.9 years (17,484 days).
Specimen C3N-04382-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1be1a5ee-fdb9-4f53-b679-e9bc116fb37f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04382-31 (Blood Derived Normal), aliquot CPT0241700002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e5bb2f3-16d2-4d92-a3d7-702083594856

The open-access MAF lists 638 somatic variants for this specimen: 452 protein-altering or splice-affecting, 114 silent, 72 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 384, Silent 114, Intron 32, Nonsense Mutation 29, Frame Shift Del 16, Splice Site 13, RNA 13, 3'UTR 9, Splice Region 7, 3'Flank 7, 5'Flank 6, 5'UTR 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>T p.G509V (on ENST00000288602 / NM_001374244.1; = p.G469V on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/468 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- RB1 | c.1499-1G>T p.X500_splice | Splice Site (SNP) | VAF 12/52 reads (23%) | hotspot (GDC flag); catalogued as rs1485450031, CS011568, CS941539, COSV57296073, COSV57310062, COSV57310173; called by muse, mutect2, varscan2
- TP53 | c.839G>T p.R280I | Missense Mutation (SNP) | VAF 149/583 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.2763C>A p.Y921* | Nonsense Mutation (SNP) | VAF 102/489 reads (21%) | catalogued as COSV70026255; called by muse, mutect2, varscan2
- ABCB4 | c.2177C>A p.P726Q | Missense Mutation (SNP) | VAF 83/342 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM105798, COSV99710562; called by muse, mutect2, varscan2
- ABCF2 | c.899A>G p.N300S | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.026); catalogued as rs1224494185; called by muse, mutect2, varscan2
- ADAMTS10 | c.3086G>T p.R1029L | Missense Mutation (SNP) | VAF 79/287 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1203849682, COSV54356315; called by muse, mutect2, varscan2
- ADCY10 | c.254-1G>T p.X85_splice | Splice Site (SNP) | VAF 68/278 reads (24%) | catalogued as rs757462903; called by mutect2, varscan2
- ADH1B | c.187C>A p.P63T | Missense Mutation (SNP) | VAF 59/291 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV59295234; called by muse, mutect2, varscan2
- AKR1B15 | c.881C>T p.T294I | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as rs1354176226; called by muse, mutect2
- AP3S1 | c.197G>T p.R66I | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57473704; called by muse, mutect2
- ARHGEF18 | c.2675G>A p.R892Q (on ENST00000359920 / NM_001130955.2; = p.R788Q on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/259 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.382); catalogued as rs1252268167; called by muse, mutect2, varscan2
- ARMC5 | c.2575C>T p.H859Y | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.476); catalogued as rs776659857; called by muse, mutect2, varscan2
- ARMH1 | c.921-8C>T | Splice Region (SNP) | VAF 29/243 reads (12%) | catalogued as rs1263323249; called by muse, mutect2, varscan2
- ASCL4 | c.29G>C p.R10P | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV60817064; called by muse, mutect2, varscan2
- ATG2A | c.3709G>A p.V1237I | Missense Mutation (SNP) | VAF 27/278 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as rs145632022, COSV65968996; called by muse, mutect2, varscan2
- AXIN2 | c.1394G>T p.R465L | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.313); catalogued as rs764640447, COSV61058597; called by muse, mutect2
- BCL11A | c.1522G>T p.A508S (on ENST00000335712 / NM_001365609.1; = p.A542S on NM_018014.4) | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1239160421, COSV59627719; called by muse, mutect2, varscan2
- BRAF | c.1525G>T p.G509* (on ENST00000288602 / NM_001374244.1; = p.G469* on NM_004333.6 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 36/467 reads (8%) | catalogued as rs121913357, BM1457681, COSV56070557, COSV56082352, COSV99953015; ClinVar: uncertain significance; called by muse, mutect2
- C6orf58 | c.95T>C p.L32P | Missense Mutation (SNP) | VAF 76/358 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61667281; called by muse, mutect2, varscan2
- CCDC110 | c.116-2A>G p.X39_splice | Splice Site (SNP) | VAF 19/144 reads (13%) | catalogued as rs1554033701; called by muse, mutect2, varscan2
- CCDC178 | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55761954; called by muse, mutect2
- CCDC91 | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | catalogued as COSV100081061; called by muse, mutect2, varscan2
- CDCA5 | c.411G>C p.L137= | Splice Region (SNP) | VAF 46/362 reads (13%) | catalogued as rs1186059372; called by muse, mutect2, varscan2
- CDH3 | c.1796-2del p.X599_splice | Splice Site (DEL) | VAF 109/510 reads (21%) | catalogued as CS103100; called by mutect2, pindel*, varscan2
- CEP131 | c.1783G>T p.A595S (on ENST00000269392 / NM_001319228.2; = p.A592S on NM_014984.4) | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.107); catalogued as COSV53950862; called by muse, mutect2, varscan2
- CHID1 | c.436A>G p.I146V | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.058); catalogued as rs1268922302; called by muse, mutect2, varscan2
- CHRNA4 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 60/326 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.026); catalogued as rs1389368921; called by muse, mutect2, varscan2
- CLDN17 | c.252G>A p.M84I | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54522410; called by muse, mutect2, varscan2
- COL18A1 | c.19G>A p.G7S | Missense Mutation (SNP) | VAF 59/260 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV62704261; called by muse, mutect2, varscan2
- COL19A1 | c.3340C>A p.Q1114K | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.604); catalogued as COSV59589381; called by muse, mutect2, varscan2
- COL6A6 | c.1857G>A p.M619I | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV62037091; called by muse, mutect2, varscan2
- CRADD | c.504del p.Q169Sfs*44 | Frame Shift Del (DEL) | VAF 51/286 reads (18%) | catalogued as COSV100257852; called by mutect2, pindel, varscan2
- CRMP1 | c.1214C>T p.S405L | Missense Mutation (SNP) | VAF 36/315 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61479555, COSV61480029; called by muse, mutect2, varscan2
- CSMD1 | c.9909C>G p.C3303W (on ENST00000520002; = p.C3302W on NM_033225.6) | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100144966; called by muse, mutect2, varscan2
- CTDP1 | c.2369C>T p.P790L | Missense Mutation (SNP) | VAF 91/327 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV50003133; called by muse, mutect2, varscan2
- CTNNA2 | c.1498G>A p.V500M | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs775975399, COSV58134573; called by muse, mutect2, varscan2
- DMWD | c.365G>T p.G122V | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.044); catalogued as rs1291920059; called by muse, mutect2, varscan2
- DNHD1 | c.10363C>A p.P3455T | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.863); catalogued as COSV54441298; called by muse, mutect2, varscan2
- DPP6 | c.1228C>A p.L410I (on ENST00000377770 / NM_001364500.2; = p.L348I on NM_001936.5) | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.765); catalogued as COSV100127976; called by muse, mutect2, varscan2
- EFHC2 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.184); catalogued as rs772582437, COSV101375491, COSV101375579; called by muse, mutect2, varscan2
- FAT3 | c.11800G>C p.D3934H | Missense Mutation (SNP) | VAF 55/285 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99962311; called by muse, mutect2, varscan2
- FGF3 | c.37G>T p.E13* | Nonsense Mutation (SNP) | VAF 51/417 reads (12%) | catalogued as rs1554981448; called by muse, varscan2
- FHAD1 | c.3320C>T p.T1107M | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs868587232; called by muse, mutect2
- FLG | c.2690G>A p.R897H | Missense Mutation (SNP) | VAF 224/850 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.202); catalogued as rs200062706, COSV64241578; called by muse, mutect2, varscan2
- FLG2 | c.5800C>A p.H1934N | Missense Mutation (SNP) | VAF 148/494 reads (30%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.608); catalogued as rs148279391; called by muse, mutect2, varscan2
- FNDC1 | c.4514C>A p.P1505H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.97); catalogued as rs1211940249; called by muse, mutect2, varscan2
- GAL3ST3 | c.523G>T p.V175L | Missense Mutation (SNP) | VAF 50/230 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV61749061; called by muse, mutect2, varscan2
- GALNT12 | c.296G>T p.R99L | Missense Mutation (SNP) | VAF 59/260 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as COSV66662641; called by muse, mutect2, varscan2
- GTF2E2 | c.134A>G p.H45R | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1563513580; called by muse, mutect2, varscan2
- GYS2 | c.1736G>A p.R579H | Missense Mutation (SNP) | VAF 46/280 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs768287810, COSV99679722; called by muse, mutect2, varscan2
- HERC1 | c.4514A>G p.Y1505C | Missense Mutation (SNP) | VAF 77/220 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs567272238, COSV71250251; called by muse, mutect2, varscan2
- HOXA10 | c.151G>T p.G51C | Missense Mutation (SNP) | VAF 120/400 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as rs1461860989; called by muse, mutect2, varscan2
- HOXA7 | c.146C>G p.S49W | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV54217337; called by muse, mutect2, varscan2
- HTR3A | c.154G>A p.V52M | Missense Mutation (SNP) | VAF 58/282 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149608465; called by muse, mutect2, varscan2
- IFNA4 | c.307A>G p.S103G | Missense Mutation (SNP) | VAF 64/430 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV101427067; called by muse, mutect2, varscan2
- IKZF3 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 66/375 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as rs748075678; called by muse, mutect2, varscan2
- IL1R1 | c.1705G>T p.G569W | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV52107374; called by muse, mutect2, varscan2
- IMP4 | c.196+7A>G | Splice Region (SNP) | VAF 24/172 reads (14%) | catalogued as rs1266789317; called by muse, mutect2, varscan2
- INO80B | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 48/292 reads (16%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.497); catalogued as rs867547292; called by muse, mutect2, varscan2
- ITPRID1 | c.2506C>A p.L836I | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.098); catalogued as COSV60071670; called by muse, mutect2, varscan2
- KCNH3 | c.361G>T p.G121W | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57793518; called by muse, mutect2
- KCNJ12 | c.100G>C p.G34R | Missense Mutation (SNP) | VAF 42/351 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs781879848, COSV100055999, COSV59165493; called by muse, mutect2, varscan2
- KCNV1 | c.1267C>A p.P423T | Missense Mutation (SNP) | VAF 104/249 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52084642; called by muse, mutect2, varscan2
- KEAP1 | c.1777G>T p.E593* | Nonsense Mutation (SNP) | VAF 51/228 reads (22%) | catalogued as COSV50390346, COSV50582630; called by muse, mutect2, varscan2
- KIF5A | c.2560C>G p.L854V | Missense Mutation (SNP) | VAF 117/523 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV54051603; called by muse, mutect2, varscan2
- KITLG | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99933091; called by muse, mutect2, varscan2
- KLK4 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 77/288 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV60675929; called by muse, mutect2, varscan2
- KRT1 | c.884A>T p.Y295F | Missense Mutation (SNP) | VAF 63/320 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs1367982890; called by muse, mutect2, varscan2
- KRT3 | c.1411C>G p.L471V | Missense Mutation (SNP) | VAF 97/440 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58815707; called by muse, mutect2, varscan2
- LAMA4 | c.368G>T p.R123M | Missense Mutation (SNP) | VAF 87/497 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as COSV100037785; called by muse, mutect2, varscan2
- LILRA6 | c.637C>A p.P213T | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.742); catalogued as rs778774071; called by mutect2, varscan2
- LILRB3 | c.637C>A p.P213T | Missense Mutation (SNP) | VAF 35/283 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.227); catalogued as rs767627433; called by muse, mutect2, varscan2
- LINC00587 | n.351G>T | Splice Region (SNP) | VAF 15/63 reads (24%) | catalogued as rs1380637862; called by muse, mutect2, varscan2
- LRP1B | c.6396G>T p.E2132D | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101260528; called by muse, mutect2, varscan2
- LRRK2 | c.5675C>G p.S1892* | Nonsense Mutation (SNP) | VAF 35/247 reads (14%) | catalogued as COSV54164445; called by muse, mutect2, varscan2
- LUZP1 | c.2996T>G p.V999G | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV100034903; called by muse, mutect2, varscan2
- MAGEC1 | c.1710G>C p.Q570H | Missense Mutation (SNP) | VAF 95/226 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.447); catalogued as rs766075324; called by muse, mutect2, varscan2
- MAPK7 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 61/236 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.061); catalogued as rs756030990, COSV55189889; called by muse, mutect2, varscan2
- MEGF10 | c.2239C>G p.P747A | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as COSV57257157; called by muse, mutect2
- MIOS | c.2573G>A p.C858Y | Missense Mutation (SNP) | VAF 49/252 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375071960; called by muse, mutect2, varscan2
- MS4A2 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 57/579 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.153); catalogued as COSV54012672; called by muse, mutect2
- MUC16 | c.19900G>T p.V6634F | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.119); catalogued as COSV67452862; called by muse, mutect2, varscan2
- MUC5AC | c.35G>T p.W12L | Missense Mutation (SNP) | VAF 40/322 reads (12%) | SIFT deleterious (0); catalogued as COSV62253631; called by muse, mutect2, varscan2
- MYADML2 | c.740T>A p.V247E | Missense Mutation (SNP) | VAF 82/334 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1408824305; called by muse, mutect2, varscan2
- MYO3B | c.995G>A p.R332K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.034); catalogued as rs1016535152; called by muse, mutect2, varscan2
- MYT1 | c.3310G>T p.E1104* | Nonsense Mutation (SNP) | VAF 39/196 reads (20%) | catalogued as COSV60508008; called by muse, mutect2, varscan2
- NEURL3 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.109); catalogued as COSV100182473; called by muse, mutect2, varscan2
- NFE2L2 | c.293G>C p.G98A | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV67960755; called by muse, mutect2
- NLRP14 | c.2404G>T p.G802* | Nonsense Mutation (SNP) | VAF 42/273 reads (15%) | catalogued as COSV100205557, COSV55069017; called by muse, mutect2, varscan2
- NPHS2 | c.29G>T p.R10M | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as CM085593; called by muse, mutect2, varscan2
- NPVF | c.335C>A p.S112Y | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV56060154, COSV56061894; called by muse, mutect2, varscan2
- NTRK3 | c.669G>T p.E223D | Missense Mutation (SNP) | VAF 82/269 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.901); catalogued as COSV58126616; called by muse, mutect2, varscan2
- OR14A16 | c.479G>T p.G160V | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.135); catalogued as COSV62927031; called by muse, mutect2, varscan2
- OR1K1 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 40/269 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV52956692; called by muse, mutect2, varscan2
- OR2B3 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 58/303 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65850971; called by muse, mutect2, varscan2
- OR2T1 | c.252C>A p.Y84* | Nonsense Mutation (SNP) | VAF 27/152 reads (18%) | catalogued as rs1296415026, COSV63541934; called by muse, mutect2, varscan2
- OR3A2 | c.631G>T p.V211L | Missense Mutation (SNP) | VAF 111/418 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV68694966; called by muse, mutect2, varscan2
- OR52B4 | c.118G>T p.A40S | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.47); catalogued as COSV68769203, COSV68769408; called by mutect2, varscan2
- OR5B21 | c.476C>G p.A159G | Missense Mutation (SNP) | VAF 51/273 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV64481686; called by muse, mutect2, varscan2
- OR5D13 | c.635G>T p.S212I | Missense Mutation (SNP) | VAF 15/207 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV100686939; called by muse, mutect2
- PCARE | c.535C>A p.P179T | Missense Mutation (SNP) | VAF 128/690 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV59056750; called by muse, mutect2, varscan2
- PCDH15 | c.2993C>A p.P998H | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100224411; called by muse, mutect2
- PCDHGA8 | c.1638G>T p.M546I | Missense Mutation (SNP) | VAF 54/502 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV53959197, COSV54050245; called by muse, mutect2, varscan2
- PCK1 | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100100269; called by muse, mutect2
- PDE10A | c.1399C>A p.R467S | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs777040046, COSV63103078; called by muse, mutect2, varscan2
- PDZD4 | c.969G>T p.Q323H | Missense Mutation (SNP) | VAF 71/190 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV51248931; called by muse, mutect2, varscan2
- PLD2 | c.944G>A p.R315K | Missense Mutation (SNP) | VAF 51/223 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1263645687, COSV99561947; called by muse, mutect2, varscan2
- PLXNA1 | c.4711G>C p.E1571Q | Missense Mutation (SNP) | VAF 43/250 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99303167; called by muse, mutect2, varscan2
- PLXNB3 | c.2471C>G p.P824R | Missense Mutation (SNP) | VAF 110/206 reads (53%) | SIFT tolerated (0.43); PolyPhen benign (0.178); catalogued as COSV100737885; called by muse, mutect2, varscan2
- PROS1 | c.1142G>A p.G381D | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1223579199, CM951055, CM961180; called by muse, mutect2, varscan2
- PRR16 | c.499C>A p.P167T (on ENST00000407149 / NM_001300783.2; = p.P144T on NM_016644.2) | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65402304, COSV65407760; called by muse, mutect2, varscan2
- PTMA | c.109G>T p.G37W | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100398481; called by muse, mutect2, varscan2
- PTPRD | c.2864C>A p.T955N | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as rs763256154, COSV61977473, COSV61980890; called by muse, mutect2, varscan2
- RAPGEF6 | c.2291A>T p.Y764F | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as COSV57243642; called by muse, mutect2, varscan2
- RGR | c.784C>G p.P262A | Missense Mutation (SNP) | VAF 154/656 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV63894317; called by muse, mutect2, varscan2
- SHANK2 | c.1214G>T p.R405L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99575836; called by mutect2, varscan2
- SLC28A3 | c.1123G>T p.V375L | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.775); catalogued as COSV66152424; called by muse, mutect2, varscan2
- SLC2A14 | c.871del p.R291Dfs*70 | Frame Shift Del (DEL) | VAF 42/395 reads (11%) | catalogued as COSV100533861, COSV61588486; called by mutect2, varscan2
- SMARCA4 | c.1630C>T p.Q544* | Nonsense Mutation (SNP) | VAF 160/617 reads (26%) | catalogued as COSV60792986; called by muse, mutect2, varscan2
- STAB2 | c.3969C>A p.C1323* | Nonsense Mutation (SNP) | VAF 20/252 reads (8%) | catalogued as COSV101185662; called by muse, mutect2
- SYNDIG1 | c.105C>A p.S35R | Missense Mutation (SNP) | VAF 31/288 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV65236180; called by muse, mutect2, varscan2
- SYNE1 | c.916G>A p.A306T (on ENST00000367255 / NM_182961.4; = p.A313T on NM_033071.3) | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs754715013; called by muse, mutect2, varscan2
- TBPL2 | c.424G>T p.V142F | Missense Mutation (SNP) | VAF 46/400 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.043); catalogued as rs777711783; called by muse, mutect2, varscan2
- TCF7 | c.291C>A p.D97E | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.242); catalogued as rs764650996; called by muse, mutect2, varscan2
- TLR4 | c.164C>A p.S55* (on ENST00000355622 / NM_138554.5; = p.S15* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 28/191 reads (15%) | catalogued as COSV62922635; called by muse, mutect2, varscan2
- TMEM161B | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.31); catalogued as COSV53510133; called by muse, mutect2
- TPBG | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as rs761188317; called by muse, mutect2, varscan2
- TYRP1 | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 68/330 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66358047; called by muse, mutect2, varscan2
- WDFY4 | c.1606G>A p.V536I | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV57433107; called by muse, mutect2, varscan2
- XIRP2 | c.2011G>A p.E671K (on ENST00000628543; = p.E846K on NM_152381.6) | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774734983, COSV54733876; called by muse, mutect2, varscan2
- ZFAND4 | c.82A>G p.M28V | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs748021246; called by muse, mutect2, varscan2
- ZFHX4 | c.3027C>G p.N1009K | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51474567; called by muse, mutect2, varscan2
- ZFHX4 | c.9289G>C p.A3097P | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV50980992; called by muse, mutect2
- ZNF112 | c.1858C>T p.R620W (on ENST00000337401 / NM_001083335.2; = p.R614W on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 122/585 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as rs770383816, COSV61620053; called by muse, mutect2, varscan2
- ZNF425 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as rs1198498442, COSV65202425; called by muse, mutect2, varscan2
- ZNF570 | c.627G>T p.K209N | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as COSV57579626; called by muse, mutect2, varscan2
- ZNF804B | c.961C>G p.H321D | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as COSV60817510; called by muse, mutect2
- ZNF91 | c.2662G>A p.D888N | Missense Mutation (SNP) | VAF 55/189 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as rs1359369958; called by muse, mutect2, varscan2
- AC020637.1 | n.798C>T | Splice Region (SNP) | VAF 15/131 reads (11%) | called by muse, mutect2, varscan2
- ACKR3 | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- ACSM2A | c.402G>T p.M134I (on ENST00000219054; = p.M55I on NM_001308169.2) | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- ADAM33 | c.1469del p.G490Afs*56 | Frame Shift Del (DEL) | VAF 20/132 reads (15%) | called by mutect2, pindel, varscan2
- ADAMTS1 | c.2165C>A p.S722Y | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ADGRF4 | c.1545G>T p.M515I | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ADORA1 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- AHI1 | c.135+8A>T | Splice Region (SNP) | VAF 40/188 reads (21%) | called by muse, mutect2, varscan2
- ALS2 | c.437C>G p.P146R | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ANGPT4 | c.337A>T p.R113W | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- ANK1 | c.5045G>T p.R1682L | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ANK2 | c.10698G>T p.Q3566H | Missense Mutation (SNP) | VAF 95/510 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- ANKRD33B | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 18/82 reads (22%) | called by muse, varscan2
- ANKRD36B | c.950del p.G317Dfs*26 | Frame Shift Del (DEL) | VAF 147/592 reads (25%) | called by mutect2, pindel, varscan2
- AP2A2 | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 58/266 reads (22%) | called by muse, mutect2, varscan2
- AP3S1 | c.196A>T p.R66* | Nonsense Mutation (SNP) | VAF 17/136 reads (13%) | called by muse, mutect2
- ARAP1 | c.2835G>C p.W945C (on ENST00000393609 / NM_001040118.2; = p.W700C on NM_015242.4) | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARFGEF3 | c.1024G>T p.V342L | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ARHGAP19 | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 115/449 reads (26%) | called by muse, mutect2, varscan2
- ARHGAP36 | c.650_651del p.Q217Pfs*23 | Frame Shift Del (DEL) | VAF 41/114 reads (36%) | called by mutect2, pindel, varscan2
- ARID4A | c.3671-2A>T p.X1224_splice | Splice Site (SNP) | VAF 109/331 reads (33%) | called by muse, mutect2, varscan2
- ARMCX3 | c.562A>T p.N188Y | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARR3 | c.374C>G p.T125R | Missense Mutation (SNP) | VAF 44/211 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASXL3 | c.4541T>C p.V1514A | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2
- ATP8B4 | c.560C>A p.A187E | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2
- ATP9A | c.228G>C p.Q76H | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ATR | c.6448T>G p.C2150G | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ATXN1 | c.1081G>T p.V361L | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATXN7L1 | c.820A>T p.N274Y | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AZGP1 | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- B3GALT6 | c.978G>T p.E326D | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BAX | c.139del p.L47Wfs*13 | Frame Shift Del (DEL) | VAF 16/75 reads (21%) | called by mutect2, pindel, varscan2
- BIRC6 | c.11854G>C p.G3952R | Missense Mutation (SNP) | VAF 45/228 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- BPI | c.232G>T p.G78W (on ENST00000262865; = p.G74W on NM_001725.3) | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRINP2 | c.745C>G p.Q249E | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- C10orf67 | c.1571G>T p.G524V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- C10orf71 | c.1343C>A p.T448N | Missense Mutation (SNP) | VAF 80/253 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C11orf45 | c.46T>A p.S16T | Missense Mutation (SNP) | VAF 71/319 reads (22%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- C1orf87 | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 29/239 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- C4orf47 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2
- CABIN1 | c.1431G>T p.E477D | Missense Mutation (SNP) | VAF 185/449 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1E | c.2626C>A p.L876M | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2
- CASP14 | c.707G>T p.R236L | Missense Mutation (SNP) | VAF 52/238 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- CCDC168 | c.12592C>A p.Q4198K | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- CCDC63 | c.1185G>A p.M395I | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC71 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 78/326 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- CCDC88B | c.1797G>T p.Q599H | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- CDH2 | c.2105A>T p.Q702L | Missense Mutation (SNP) | VAF 34/311 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- CFAP92 | c.2301del p.S768Hfs*49 | Frame Shift Del (DEL) | VAF 13/97 reads (13%) | called by mutect2, pindel, varscan2
- CHD3 | c.2062A>G p.M688V | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHEK1 | c.787A>T p.R263* | Nonsense Mutation (SNP) | VAF 14/81 reads (17%) | called by muse, mutect2, varscan2
- CKMT2 | c.46C>A p.L16M | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CKMT2 | c.47T>A p.L16Q | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CLASP1 | c.3517C>A p.L1173M | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CLEC16A | c.2573A>T p.Q858L | Missense Mutation (SNP) | VAF 51/457 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- CLEC9A | c.125T>G p.V42G | Missense Mutation (SNP) | VAF 39/263 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CLK2 | c.1283G>T p.G428V (on ENST00000368361 / NM_001294339.2; = p.G427V on NM_003993.4) | Missense Mutation (SNP) | VAF 62/286 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CMIP | c.2002A>G p.S668G (on ENST00000537098 / NM_198390.2; = p.S574G on NM_030629.3) | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- CNOT1 | c.2046T>G p.N682K | Missense Mutation (SNP) | VAF 32/296 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL11A1 | c.4914_4915insA p.C1639Mfs*2 | Frame Shift Ins (INS) | VAF 27/228 reads (12%) | called by mutect2, pindel, varscan2
- COL14A1 | c.4741G>A p.G1581R | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A5 | c.4544G>A p.G1515D | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSNK1A1 | c.268A>G p.M90V | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- CXCL5 | c.140T>A p.L47Q | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYRIA | c.686T>A p.V229D | Missense Mutation (SNP) | VAF 37/340 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CYYR1 | c.260G>A p.C87Y | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DACT2 | c.100G>T p.G34W | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- DLK1 | c.303G>T p.R101S | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- DLL1 | c.255del p.V86Cfs*37 | Frame Shift Del (DEL) | VAF 76/426 reads (18%) | called by mutect2, pindel, varscan2
- DMD | c.6197C>G p.A2066G | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- DNAH10 | c.10726G>T p.E3576* (on ENST00000409039; = p.E3515* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 39/164 reads (24%) | called by muse, mutect2, varscan2
- DNHD1 | c.11819T>C p.L3940S | Missense Mutation (SNP) | VAF 36/359 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- DPYSL5 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DTNA | c.1473G>T p.Q491H | Missense Mutation (SNP) | VAF 109/550 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DTYMK | c.331-1G>A p.X111_splice | Splice Site (SNP) | VAF 17/159 reads (11%) | called by muse, mutect2
- EDAR | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 58/259 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EP400 | c.5263G>T p.G1755C | Missense Mutation (SNP) | VAF 129/424 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ERCC6 | c.1527G>T p.K509N | Missense Mutation (SNP) | VAF 74/309 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- ERV3-1 | c.1801A>C p.T601P | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- ETFA | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 67/203 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- ETFA | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 68/207 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- EYA2 | c.970G>T p.D324Y | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EYS | c.3950C>A p.T1317K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.15); called by muse, mutect2
- FAM110D | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- FAM120B | c.1789A>T p.S597C | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- FAM71F2 | c.529G>T p.G177C | Missense Mutation (SNP) | VAF 52/247 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FANCE | c.369G>C p.Q123H | Missense Mutation (SNP) | VAF 62/343 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FAT3 | c.3923C>A p.P1308H | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- FBXO33 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 121/429 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- FBXW10 | c.1847+1G>A p.X616_splice | Splice Site (SNP) | VAF 34/160 reads (21%) | called by muse, mutect2
- FBXW9 | c.267G>T p.E89D | Missense Mutation (SNP) | VAF 76/250 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- FCGBP | c.10196G>A p.R3399H | Missense Mutation (SNP) | VAF 203/827 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FGF13 | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 122/396 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLRT2 | c.752G>A p.G251D | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.291); called by muse, mutect2
- FOXD4L4 | c.862G>C p.A288P | Missense Mutation (SNP) | VAF 238/1459 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- FOXP2 | c.2105A>T p.D702V | Missense Mutation (SNP) | VAF 30/247 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- FRRS1 | c.156C>A p.Y52* | Nonsense Mutation (SNP) | VAF 30/223 reads (13%) | called by muse, mutect2, varscan2
- FRYL | c.1397G>T p.G466V | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FSIP2 | c.11200C>A p.Q3734K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- FSIP2 | c.13220A>G p.N4407S | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- FYB2 | c.640T>A p.S214T | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.96); PolyPhen benign (0.001); called by muse, mutect2
- GABRE | c.1201C>A p.H401N | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.192); called by muse, mutect2
- GALNT13 | c.1307T>C p.V436A | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- GBP5 | c.1713G>T p.Q571H | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.378); called by muse, mutect2
- GJD4 | c.784G>T p.A262S | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- GLI3 | c.1577C>T p.P526L | Missense Mutation (SNP) | VAF 32/338 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- GOLGA6L1 | c.1574T>G p.I525R | Missense Mutation (SNP) | VAF 131/1180 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- GPIHBP1 | c.340T>A p.C114S | Missense Mutation (SNP) | VAF 135/348 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPR174 | c.223A>T p.R75W | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR179 | c.3809del p.T1270Rfs*11 (on ENST00000621958; = p.T1269Rfs*11 on NM_001004334.4) | Frame Shift Del (DEL) | VAF 27/251 reads (11%) | called by mutect2, pindel, varscan2
- GRHL2 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 184/526 reads (35%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- GSDMB | c.890T>A p.V297E (on ENST00000418519 / NM_001165958.1; = p.V275E on NM_018530.2) | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); called by muse, mutect2
- HECA | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2
- HID1 | c.408G>T p.E136D | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HYDIN | c.2918C>A p.P973H | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, varscan2
- IDO1 | c.656-1G>T p.X219_splice | Splice Site (SNP) | VAF 66/136 reads (49%) | called by muse, mutect2, varscan2
- IFFO2 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IGFBP3 | c.316G>T p.A106S | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- IGHG1 | c.340+1G>T p.X114_splice | Splice Site (SNP) | VAF 147/534 reads (28%) | called by muse, mutect2, varscan2
- IGKV1D-43 | c.291C>G p.I97M | Missense Mutation (SNP) | VAF 123/948 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- IL23A | c.404T>C p.L135P | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ILVBL | c.935G>A p.G312D | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- INTS4 | c.2784G>A p.W928* | Nonsense Mutation (SNP) | VAF 34/329 reads (10%) | called by muse, mutect2, varscan2
- INVS | c.1979G>A p.G660E | Missense Mutation (SNP) | VAF 63/600 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ISLR2 | c.335C>G p.S112C | Missense Mutation (SNP) | VAF 94/241 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ITGA2B | c.903G>T p.L301F | Missense Mutation (SNP) | VAF 97/404 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ITGAM | c.3459G>T p.Q1153H (on ENST00000648685 / NM_001145808.2; = p.Q1152H on NM_000632.4) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ITGAV | c.808G>T p.V270F | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- ITGAX | c.1804C>A p.L602M | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ITK | c.67C>A p.P23T | Missense Mutation (SNP) | VAF 47/414 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNA2 | c.1390G>T p.G464C | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- KCNH7 | c.1717A>T p.I573F | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNQ1 | c.1562A>T p.Q521L | Missense Mutation (SNP) | VAF 82/468 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- KDM4C | c.133G>T p.G45C | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA0586 | c.1651G>T p.D551Y (on ENST00000619416 / NM_001244190.2; = p.D619Y on NM_001244189.2) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- KIRREL3 | c.2053C>A p.Q685K | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KNCN | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KNL1 | c.6496G>T p.G2166C (on ENST00000346991 / NM_170589.5; = p.G2140C on NM_144508.5) | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- KRTAP22-2 | c.47G>T p.S16I | Missense Mutation (SNP) | VAF 35/196 reads (18%) | PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- LAPTM4B | c.202G>C p.G68R | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- LIFR | c.949A>G p.T317A | Missense Mutation (SNP) | VAF 60/218 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LMNB2 | c.692_693delinsT p.R231Lfs*61 | Frame Shift Del (DEL) | VAF 25/196 reads (13%) | called by pindel, varscan2*
- LRP2 | c.3430+1G>T p.X1144_splice | Splice Site (SNP) | VAF 31/285 reads (11%) | called by muse, mutect2, varscan2
- LRRC8B | c.609A>T p.K203N | Missense Mutation (SNP) | VAF 83/292 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEC2 | c.931A>C p.K311Q | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- MAP2 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MAP6 | c.2437C>T p.P813S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- MATR3 | c.1511C>T p.P504L | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MBNL2 | c.312G>T p.M104I | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2
- MCRS1 | c.20G>T p.G7V | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MED13L | c.2091C>A p.D697E | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MGAM2 | c.1168G>T p.D390Y | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- MKRN1 | c.1312G>T p.E438* | Nonsense Mutation (SNP) | VAF 74/419 reads (18%) | called by muse, mutect2, varscan2
- MPEG1 | c.1197G>T p.K399N | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRC2 | c.3718G>T p.G1240W | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MRGPRX1 | c.413T>G p.L138R | Missense Mutation (SNP) | VAF 39/352 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.275); called by muse, mutect2
- MRGPRX1 | c.411C>A p.H137Q | Missense Mutation (SNP) | VAF 39/349 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- MSGN1 | c.135G>T p.Q45H | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC16 | c.39008C>T p.P13003L | Missense Mutation (SNP) | VAF 82/261 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- MUC4 | c.12149C>G p.P4050R | Missense Mutation (SNP) | VAF 71/823 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- MUC5B | c.3577C>A p.L1193M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- MYH1 | c.3067A>C p.T1023P | Missense Mutation (SNP) | VAF 73/320 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- MYH2 | c.2149A>T p.S717C | Missense Mutation (SNP) | VAF 72/323 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- MYO15B | c.4248G>T p.M1416I | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MYRFL | c.2513G>T p.S838I | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- NAV3 | c.3830G>C p.S1277T | Missense Mutation (SNP) | VAF 84/363 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NCOA3 | c.2147G>T p.C716F | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- NGF | c.668T>C p.I223T | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NKD2 | c.817C>A p.P273T | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- NOMO2 | c.2121G>T p.R707S | Missense Mutation (SNP) | VAF 41/284 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.078); called by mutect2, varscan2
- NOMO3 | c.2121G>T p.R707S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.118); called by mutect2, varscan2
- NPAP1 | c.2465C>A p.T822N | Missense Mutation (SNP) | VAF 76/293 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NPC1L1 | c.2039T>C p.V680A | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- NR2C2 | c.611G>T p.C204F (on ENST00000393102; = p.C223F on NM_003298.5) | Missense Mutation (SNP) | VAF 17/222 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2
- NRXN1 | c.3505G>C p.D1169H | Missense Mutation (SNP) | VAF 51/326 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- NUP205 | c.1525A>G p.I509V | Missense Mutation (SNP) | VAF 40/413 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- NUTM2F | c.221G>T p.S74I | Missense Mutation (SNP) | VAF 77/382 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- NYNRIN | c.5543G>T p.G1848V | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OR10G3 | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR1K1 | c.446C>A p.A149E | Missense Mutation (SNP) | VAF 41/272 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- OR2AJ1 | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- OR2T1 | c.253C>A p.L85M | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- OR4A15 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 51/269 reads (19%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OR4K14 | c.570C>G p.C190W | Missense Mutation (SNP) | VAF 61/234 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR51V1 | c.726G>T p.Q242H | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- OR52N4 | c.309G>T p.M103I | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- OR56A5 | c.833T>A p.L278Q | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5AP2 | c.119T>C p.I40T | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2
- OR5D13 | c.880C>A p.L294I | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2
- OR8I2 | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- OR8J3 | c.835A>G p.T279A | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ORAI1 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 130/419 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- OS9 | c.647G>T p.C216F | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OTOP1 | c.900G>T p.Q300H | Missense Mutation (SNP) | VAF 64/300 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OTUD6A | c.833del p.G278Afs*31 | Frame Shift Del (DEL) | VAF 17/73 reads (23%) | called by mutect2, pindel, varscan2
- OVOL1 | c.699G>T p.K233N | Missense Mutation (SNP) | VAF 129/527 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- PARVG | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 43/217 reads (20%) | called by muse, mutect2, varscan2
- PCARE | c.1752C>A p.S584R | Missense Mutation (SNP) | VAF 54/223 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- PCDH10 | c.2500C>A p.L834M | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- PCDHA10 | c.1232C>G p.A411G | Missense Mutation (SNP) | VAF 55/453 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PCDHB7 | c.1772C>A p.A591E | Missense Mutation (SNP) | VAF 149/1085 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDGFRA | c.1875del p.V626* | Frame Shift Del (DEL) | VAF 66/477 reads (14%) | called by mutect2, pindel, varscan2
- PGK2 | c.440T>A p.I147K | Missense Mutation (SNP) | VAF 50/240 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- PID1 | c.466G>T p.V156L (on ENST00000354069 / NM_001330156.1; = p.V154L on NM_017933.5) | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- PKHD1L1 | c.8327A>T p.D2776V | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- PLCXD2 | c.830G>T p.G277V | Missense Mutation (SNP) | VAF 39/227 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLVAP | c.841T>A p.S281T | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- PMS1 | c.2717A>T p.H906L | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2
- POLR1A | c.3008A>G p.Y1003C | Missense Mutation (SNP) | VAF 45/255 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRMT3 | c.1399G>T p.V467F | Missense Mutation (SNP) | VAF 35/203 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- PROSER3 | c.327C>A p.F109L | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PSG6 | c.1240+1G>T p.X414_splice | Splice Site (SNP) | VAF 63/572 reads (11%) | called by muse, mutect2, varscan2
- PTPRD | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 80/331 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PTPRU | c.1313G>T p.C438F | Missense Mutation (SNP) | VAF 123/610 reads (20%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- QSER1 | c.1390del p.E464Sfs*3 (on ENST00000399302; = p.E593Sfs*3 on NM_001076786.3) | Frame Shift Del (DEL) | VAF 38/177 reads (21%) | called by mutect2, pindel, varscan2
- RBM17 | c.401G>A p.R134K | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- REG3A | c.86C>G p.P29R | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.009); called by muse, varscan2
- RELN | c.3101C>A p.P1034H | Missense Mutation (SNP) | VAF 70/575 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RESP18 | c.671C>A p.P224Q | Missense Mutation (SNP) | VAF 31/300 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.906); called by muse, mutect2
- RHO | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 73/461 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RIPPLY3 | c.434A>T p.E145V | Missense Mutation (SNP) | VAF 60/265 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- RPL22L1 | c.76G>T p.D26Y | Missense Mutation (SNP) | VAF 54/189 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RPS14 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 41/276 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- RPS6KC1 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RYR2 | c.3046T>A p.W1016R | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- SCN3A | c.1367A>T p.Q456L | Missense Mutation (SNP) | VAF 34/267 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SCN9A | c.3533G>T p.W1178L (on ENST00000303354; = p.W1167L on NM_002977.3) | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- SECISBP2L | c.2287G>C p.A763P (on ENST00000559471 / NM_001193489.2; = p.A718P on NM_014701.4) | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SEMA5B | c.1862G>T p.C621F | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SERPINA5 | c.1129C>G p.L377V | Missense Mutation (SNP) | VAF 99/296 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SETD1B | c.4475C>T p.A1492V | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.019); called by muse, mutect2
- SGK2 | c.934C>A p.Q312K | Missense Mutation (SNP) | VAF 44/244 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- SGPP2 | c.1004T>G p.I335S | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- SHANK1 | c.1505G>T p.R502L | Missense Mutation (SNP) | VAF 70/344 reads (20%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- SHANK2 | c.1528_1530del p.L510del | In Frame Del (DEL) | VAF 42/262 reads (16%) | called by mutect2, pindel, varscan2
- SHPRH | c.4155A>T p.V1385= (on ENST00000275233 / NM_001042683.3; = p.V1389= on NM_173082.3) | Splice Region (SNP) | VAF 19/92 reads (21%) | called by muse, mutect2, varscan2
- SIDT1 | c.1198G>T p.V400L | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- SLC13A1 | c.422C>T p.T141I | Missense Mutation (SNP) | VAF 39/223 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SLC17A9 | c.447G>T p.E149D | Missense Mutation (SNP) | VAF 55/322 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SLC35F1 | c.649C>A p.L217M | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.897); called by muse, mutect2
- SLC5A1 | c.1035T>A p.C345* | Nonsense Mutation (SNP) | VAF 182/514 reads (35%) | called by muse, mutect2, varscan2
- SLC8A3 | c.2422A>T p.K808* (on ENST00000381269 / NM_183002.3; = p.K806* on NM_033262.4) | Nonsense Mutation (SNP) | VAF 19/81 reads (23%) | called by muse, mutect2, varscan2
- SLC9A4 | c.794C>A p.A265D | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- SLCO1B1 | c.724C>A p.L242I | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- SMAD2 | c.1330G>A p.G444R | Missense Mutation (SNP) | VAF 40/406 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2
- SMARCA2 | c.2385G>T p.W795C | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMG8 | c.725A>C p.K242T | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SNX25 | c.1207A>G p.K403E | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SNX31 | c.926del p.Q309Rfs*7 | Frame Shift Del (DEL) | VAF 159/490 reads (32%) | called by mutect2, pindel, varscan2
- SPACA1 | c.85G>C p.G29R | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- SPEG | c.5555C>A p.P1852H | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SPHKAP | c.3362G>A p.S1121N | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SPHKAP | c.1430T>C p.V477A | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPRY3 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 152/430 reads (35%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SPSB4 | c.117G>T p.Q39H | Missense Mutation (SNP) | VAF 41/202 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPTBN2 | c.3514del p.H1172Tfs*47 | Frame Shift Del (DEL) | VAF 57/369 reads (15%) | called by mutect2, pindel, varscan2
- SRCAP | c.2516G>T p.R839L | Missense Mutation (SNP) | VAF 47/192 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SRP72 | c.1604G>A p.G535E | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- SSC4D | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- STK32C | c.963G>A p.W321* | Nonsense Mutation (SNP) | VAF 52/198 reads (26%) | called by muse, mutect2, varscan2
- STKLD1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 39/229 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- SYNE1 | c.19905G>T p.Q6635H (on ENST00000367255 / NM_182961.4; = p.Q6564H on NM_033071.3) | Missense Mutation (SNP) | VAF 53/309 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYNE1 | c.11493G>T p.W3831C (on ENST00000367255 / NM_182961.4; = p.W3816C on NM_033071.3) | Missense Mutation (SNP) | VAF 70/354 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNJ1 | c.3293del p.G1098Vfs*95 | Frame Shift Del (DEL) | VAF 43/235 reads (18%) | called by mutect2, pindel, varscan2
- TBATA | c.503A>T p.K168I | Missense Mutation (SNP) | VAF 65/309 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- TBCCD1 | c.1351G>T p.E451* | Nonsense Mutation (SNP) | VAF 164/757 reads (22%) | called by muse, mutect2, varscan2
- TBX4 | c.1372C>A p.L458I | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); called by muse, mutect2
- TDRD5 | c.148T>C p.Y50H | Missense Mutation (SNP) | VAF 57/550 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TESPA1 | c.829C>A p.Q277K (on ENST00000316577 / NM_001098815.3; = p.Q139K on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/267 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TET1 | c.4642C>G p.P1548A | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- TEX13C | c.1192C>T p.H398Y | Missense Mutation (SNP) | VAF 193/508 reads (38%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- THOP1 | c.1257A>T p.E419D | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- THRB | c.158A>T p.Q53L | Missense Mutation (SNP) | VAF 53/451 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TLE3 | c.2014G>T p.E672* | Nonsense Mutation (SNP) | VAF 112/246 reads (46%) | called by muse, mutect2, varscan2
- TLL1 | c.2314G>A p.A772T | Missense Mutation (SNP) | VAF 23/283 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); called by muse, mutect2
- TLR8 | c.293C>A p.P98H (on ENST00000218032 / NM_138636.5; = p.P116H on NM_016610.4) | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM132A | c.886C>A p.L296M | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.735); called by muse, mutect2
- TOR4A | c.420C>G p.N140K | Missense Mutation (SNP) | VAF 81/333 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- TPSB2 | c.793G>T p.D265Y | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- TREML2 | c.437C>A p.T146N | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIML1 | c.1201A>T p.R401* | Nonsense Mutation (SNP) | VAF 13/127 reads (10%) | called by muse, mutect2, varscan2
- TTBK1 | c.3277G>T p.V1093L | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTC14 | c.1291-2A>G p.X431_splice | Splice Site (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- UACA | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- UBA6 | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UMOD | c.1424C>A p.S475Y | Missense Mutation (SNP) | VAF 51/258 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- UNC80 | c.303C>G p.H101Q | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UNC80 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2
- UNC80 | c.6747G>T p.Q2249H | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- USF3 | c.1576C>G p.L526V | Missense Mutation (SNP) | VAF 47/248 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- USP42 | c.795+2T>C p.X265_splice | Splice Site (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2
- UTP3 | c.331G>T p.G111C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- VCAN | c.4357C>A p.P1453T | Missense Mutation (SNP) | VAF 48/528 reads (9%) | SIFT tolerated (0.81); PolyPhen benign (0.007); called by muse, mutect2
- VGLL1 | c.580C>A p.Q194K | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- VWA7 | c.1200G>T p.Q400H | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- WDR45B | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 32/290 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- WHRN | c.2216G>C p.R739T | Missense Mutation (SNP) | VAF 81/405 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- WNK2 | c.5510G>T p.G1837V (on ENST00000297954 / NM_001282394.1; = p.G1800V on NM_006648.3) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- YTHDC1 | c.128A>C p.K43T | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ZAN | c.2174C>A p.T725N | Missense Mutation (SNP) | VAF 41/280 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ZBTB24 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 92/578 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- ZEB1 | c.977C>A p.P326Q | Missense Mutation (SNP) | VAF 38/343 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- ZFR | c.2720G>T p.R907L | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZFYVE1 | c.1585G>T p.D529Y | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.816); called by muse, mutect2
- ZFYVE26 | c.6400G>A p.E2134K | Missense Mutation (SNP) | VAF 49/460 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ZNF112 | c.2263G>A p.G755R (on ENST00000337401 / NM_001083335.2; = p.G749R on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 112/723 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZNF534 | c.85C>A p.Q29K | Missense Mutation (SNP) | VAF 76/565 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ZNF638 | c.109A>T p.M37L | Missense Mutation (SNP) | VAF 54/293 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- ZNF644 | c.1919C>G p.T640S | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF720 | c.305G>C p.G102A | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ZNF721 | c.1202G>C p.R401T (on ENST00000338977; = p.R413T on NM_133474.4) | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZNF768 | c.446A>T p.Y149F | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); called by muse, mutect2
- ZNF780B | c.595G>T p.G199W | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AARS1 | c.954A>T p.T318= | Silent (SNP) | VAF 143/476 reads (30%) | called by muse, mutect2, varscan2
- ABCB11 | c.3807C>T p.T1269= | Silent (SNP) | VAF 43/276 reads (16%) | catalogued as rs778800796, COSV55598618, COSV99793264; called by muse, mutect2, varscan2
- ACSF2 | c.1251A>G p.T417= | Silent (SNP) | VAF 32/257 reads (12%) | catalogued as rs1455982121, COSV51973296; called by muse, mutect2, varscan2
- ACTN2 | c.2664C>G p.L888= | Silent (SNP) | VAF 90/355 reads (25%) | catalogued as rs767852364; called by muse, mutect2, varscan2
- ADAMTS19 | c.2739C>T p.N913= | Silent (SNP) | VAF 45/172 reads (26%) | called by muse, mutect2, varscan2
- ADH7 | c.651G>T p.L217= | Silent (SNP) | VAF 50/186 reads (27%) | called by muse, mutect2, varscan2
- ANO4 | c.1065C>A p.G355= (on ENST00000392977 / NM_001286615.2; = p.G320= on NM_178826.4) | Silent (SNP) | VAF 18/254 reads (7%) | called by muse, mutect2
- ARFGEF1 | c.691C>T p.L231= | Silent (SNP) | VAF 21/175 reads (12%) | catalogued as COSV99141351; called by muse, mutect2, varscan2
- ASXL3 | c.4542G>A p.V1514= | Silent (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- ATP2B4 | c.1449G>A p.G483= | Silent (SNP) | VAF 99/452 reads (22%) | called by muse, varscan2
- AVPR1A | c.168C>A p.A56= | Silent (SNP) | VAF 78/293 reads (27%) | catalogued as rs148582333; called by muse, mutect2, varscan2
- BARHL2 | c.592C>A p.R198= | Silent (SNP) | VAF 111/523 reads (21%) | catalogued as COSV64981885; called by muse, mutect2, varscan2
- BBOX1 | c.312C>A p.L104= | Silent (SNP) | VAF 16/141 reads (11%) | catalogued as COSV54191302; called by muse, mutect2, varscan2
- BLMH | c.129G>T p.R43= | Silent (SNP) | VAF 58/303 reads (19%) | called by muse, mutect2, varscan2
- C9orf24 | c.252T>A p.P84= | Silent (SNP) | VAF 38/171 reads (22%) | catalogued as rs920316836; called by muse, mutect2, varscan2
- CACNA1A | c.6684C>A p.P2228= | Silent (SNP) | VAF 41/181 reads (23%) | called by muse, varscan2
- CADPS | c.1806G>T p.V602= | Silent (SNP) | VAF 31/183 reads (17%) | catalogued as COSV51901214; called by muse, mutect2, varscan2
- CAMKK2 | c.390C>T p.P130= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs200657087; called by muse, mutect2, varscan2
- CARMIL3 | c.2316G>A p.E772= | Silent (SNP) | VAF 19/136 reads (14%) | called by muse, mutect2
- CCDC166 | c.678C>A p.R226= | Silent (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- CCNP | c.669C>A p.P223= | Silent (SNP) | VAF 26/82 reads (32%) | called by muse, mutect2, varscan2
- CD5L | c.522G>T p.V174= | Silent (SNP) | VAF 40/454 reads (9%) | catalogued as rs1344702620; called by muse, mutect2
- CDR2 | c.1066C>T p.L356= | Silent (SNP) | VAF 38/404 reads (9%) | catalogued as rs764498774; called by muse, mutect2
- CYP2C18 | c.1410C>T p.T470= | Silent (SNP) | VAF 41/201 reads (20%) | catalogued as rs766759071; called by muse, mutect2, varscan2
- DBH | c.1038C>A p.S346= | Silent (SNP) | VAF 137/691 reads (20%) | called by muse, mutect2, varscan2
- DENND1C | c.2313G>C p.L771= | Silent (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- DGCR2 | c.669G>A p.S223= | Silent (SNP) | VAF 53/148 reads (36%) | catalogued as rs199948293; called by muse, mutect2, varscan2
- DMWD | c.366G>T p.G122= | Silent (SNP) | VAF 59/204 reads (29%) | called by muse, mutect2, varscan2
- DNAH6 | c.4935C>T p.G1645= | Silent (SNP) | VAF 24/122 reads (20%) | catalogued as rs1193812338; called by muse, mutect2, varscan2
- DNAH8 | c.1128A>T p.I376= | Silent (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2
- DSCAML1 | c.3474G>T p.R1158= (on ENST00000321322; = p.R1098= on NM_020693.4) | Silent (SNP) | VAF 23/214 reads (11%) | called by muse, mutect2, varscan2
- EFHC2 | c.1014G>T p.L338= | Silent (SNP) | VAF 26/118 reads (22%) | called by muse, mutect2, varscan2
- EPM2A | c.825G>T p.A275= | Silent (SNP) | VAF 70/344 reads (20%) | catalogued as rs762115387; called by muse, mutect2, varscan2
- FBN2 | c.4428T>C p.C1476= | Silent (SNP) | VAF 111/493 reads (23%) | called by muse, mutect2, varscan2
- FLNC | c.621G>A p.E207= | Silent (SNP) | VAF 43/224 reads (19%) | catalogued as rs1163476443; called by muse, mutect2, varscan2
- GAL3ST4 | c.753C>A p.A251= | Silent (SNP) | VAF 30/148 reads (20%) | catalogued as COSV57588457; called by muse, mutect2, varscan2
- GATAD2A | c.1254A>C p.A418= | Silent (SNP) | VAF 71/257 reads (28%) | called by muse, mutect2, varscan2
- GFRA3 | c.777G>T p.P259= | Silent (SNP) | VAF 40/216 reads (19%) | catalogued as COSV51229895; called by muse, mutect2, varscan2
- GORASP1 | c.93G>T p.A31= | Silent (SNP) | VAF 25/120 reads (21%) | catalogued as COSV100073075; called by muse, mutect2, varscan2
- GPR135 | c.471G>T p.L157= | Silent (SNP) | VAF 35/295 reads (12%) | catalogued as rs1449061219; called by muse, mutect2, varscan2
- GPR25 | c.385C>T p.L129= | Silent (SNP) | VAF 82/377 reads (22%) | catalogued as rs919971689; called by muse, mutect2, varscan2
- GPX5 | c.57G>T p.V19= | Silent (SNP) | VAF 48/238 reads (20%) | called by muse, mutect2, varscan2
- GSTM5 | c.393C>A p.L131= | Silent (SNP) | VAF 40/443 reads (9%) | called by muse, mutect2
- HAPLN1 | c.984T>A p.T328= | Silent (SNP) | VAF 30/214 reads (14%) | called by muse, mutect2, varscan2
- HBG1 | c.291G>T p.L97= | Silent (SNP) | VAF 30/483 reads (6%) | called by muse, mutect2
- HBG2 | c.291G>T p.L97= | Silent (SNP) | VAF 36/692 reads (5%) | called by muse, mutect2
- IFNA10 | c.157C>T p.L53= | Silent (SNP) | VAF 96/456 reads (21%) | catalogued as rs577001228; called by muse, mutect2, varscan2
- IGHV5-51 | c.264C>T p.T88= | Silent (SNP) | VAF 200/682 reads (29%) | called by muse, mutect2, varscan2
- ITFG2 | c.54C>G p.L18= | Silent (SNP) | VAF 21/131 reads (16%) | called by muse, mutect2, varscan2
- KAZALD1 | c.33G>A p.L11= | Silent (SNP) | VAF 89/346 reads (26%) | called by muse, mutect2, varscan2
- KDM4C | c.132G>T p.A44= | Silent (SNP) | VAF 28/128 reads (22%) | catalogued as rs531909681; called by muse, mutect2, varscan2
- KLF15 | c.579C>G p.S193= | Silent (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- KRT34 | c.315G>A p.L105= | Silent (SNP) | VAF 180/796 reads (23%) | called by muse, mutect2, varscan2
- LLGL1 | c.1233C>G p.R411= | Silent (SNP) | VAF 71/245 reads (29%) | catalogued as rs1254792005; called by muse, mutect2, varscan2
- MADD | c.1545C>T p.L515= | Silent (SNP) | VAF 116/574 reads (20%) | catalogued as rs867252008; called by muse, mutect2, varscan2
- MLXIP | c.2049C>T p.N683= | Silent (SNP) | VAF 34/167 reads (20%) | called by muse, mutect2, varscan2
- MSI2 | c.585G>C p.G195= | Silent (SNP) | VAF 27/198 reads (14%) | catalogued as rs370326926; called by muse, mutect2, varscan2
- MYH3 | c.2376G>T p.V792= | Silent (SNP) | VAF 148/593 reads (25%) | catalogued as rs1018064591; called by muse, mutect2, varscan2
- MYH7B | c.1935C>A p.P645= | Silent (SNP) | VAF 52/247 reads (21%) | called by muse, mutect2, varscan2
- NFATC1 | c.2256G>T p.P752= | Silent (SNP) | VAF 41/344 reads (12%) | catalogued as rs368749505; called by muse, mutect2, varscan2
- NKX1-1 | c.393C>A p.R131= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV70026231; called by muse, mutect2, varscan2
- NLGN1 | c.756C>G p.P252= | Silent (SNP) | VAF 114/455 reads (25%) | catalogued as rs373329830; called by muse, mutect2, varscan2
- NMU | c.51C>A p.A17= | Silent (SNP) | VAF 42/230 reads (18%) | called by muse, varscan2
- NUDT14 | c.315C>A p.A105= | Silent (SNP) | VAF 81/615 reads (13%) | called by muse, mutect2, varscan2
- OR14A16 | c.807T>A p.A269= | Silent (SNP) | VAF 25/95 reads (26%) | called by muse, mutect2, varscan2
- OR4Q2 | c.415C>A p.R139= | Silent (SNP) | VAF 16/114 reads (14%) | called by muse, mutect2, varscan2
- OR6B1 | c.831C>A p.A277= | Silent (SNP) | VAF 13/139 reads (9%) | catalogued as rs534528176, COSV68769761; called by muse, mutect2
- P2RX3 | c.1116C>A p.T372= | Silent (SNP) | VAF 35/198 reads (18%) | called by muse, mutect2, varscan2
- PANK4 | c.837G>T p.S279= | Silent (SNP) | VAF 15/152 reads (10%) | called by muse, mutect2, varscan2
- PAX7 | c.330G>T p.A110= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs141499812; called by muse, mutect2
- PDGFRA | c.771C>T p.G257= | Silent (SNP) | VAF 36/189 reads (19%) | called by muse, mutect2, varscan2
- PHKA2 | c.162G>T p.V54= | Silent (SNP) | VAF 64/359 reads (18%) | called by muse, mutect2, varscan2
- PLXNA1 | c.1611G>T p.L537= | Silent (SNP) | VAF 55/250 reads (22%) | called by muse, mutect2, varscan2
- POLD2 | c.873C>T p.P291= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as rs765420637; called by muse, mutect2, varscan2
- POM121C | c.1755G>T p.P585= (on ENST00000607367; = p.P343= on NM_001099415.3) | Silent (SNP) | VAF 17/226 reads (8%) | called by muse, mutect2
- POM121L2 | c.696C>A p.P232= | Silent (SNP) | VAF 81/391 reads (21%) | called by muse, mutect2, varscan2
- PRPH2 | c.375G>A p.S125= | Silent (SNP) | VAF 59/334 reads (18%) | catalogued as rs777764923; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1341G>T p.V447= (on ENST00000352766; = p.V368= on NM_181334.5) | Silent (SNP) | VAF 16/299 reads (5%) | catalogued as COSV100424361; called by muse, mutect2
- PRSS16 | c.138C>A p.G46= | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as rs1431722595, COSV57915243; called by muse, mutect2, varscan2
- PTGER4 | c.789C>A p.I263= | Silent (SNP) | VAF 44/146 reads (30%) | catalogued as COSV56720213, COSV56722950; called by muse, mutect2, varscan2
- PYURF | c.144C>T p.R48= | Silent (SNP) | VAF 46/418 reads (11%) | called by muse, mutect2, varscan2
- RBM33 | c.1893G>T p.P631= | Silent (SNP) | VAF 14/142 reads (10%) | catalogued as COSV100265401; called by muse, mutect2
- RESP18 | c.672G>T p.P224= | Silent (SNP) | VAF 29/277 reads (10%) | called by muse, mutect2, varscan2
- RNF165 | c.255G>A p.L85= | Silent (SNP) | VAF 71/295 reads (24%) | catalogued as rs976465163; called by muse, mutect2, varscan2
- RP1L1 | c.288G>A p.L96= | Silent (SNP) | VAF 27/195 reads (14%) | called by muse, mutect2, varscan2
- RPS14 | c.264G>T p.L88= | Silent (SNP) | VAF 41/281 reads (15%) | called by muse, mutect2, varscan2
- SCTR | c.1065C>T p.Y355= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as rs1209719740; called by muse, mutect2
- SH3PXD2A | c.2769A>C p.S923= (on ENST00000369774 / NM_001365079.1; = p.S895= on NM_014631.2) | Silent (SNP) | VAF 63/240 reads (26%) | called by muse, mutect2, varscan2
- SLC6A5 | c.1299C>A p.L433= | Silent (SNP) | VAF 100/476 reads (21%) | called by muse, mutect2, varscan2
- SMG7 | c.2355C>T p.H785= | Silent (SNP) | VAF 33/125 reads (26%) | catalogued as rs770485777; called by muse, mutect2, varscan2
- SSTR4 | c.168G>T p.L56= | Silent (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- SYCP2L | c.582C>T p.H194= | Silent (SNP) | VAF 15/133 reads (11%) | catalogued as rs781782154; called by muse, mutect2, varscan2
- SYNPO2 | c.3183A>T p.S1061= | Silent (SNP) | VAF 31/372 reads (8%) | called by muse, mutect2
- TACC2 | c.3282G>T p.P1094= | Silent (SNP) | VAF 19/92 reads (21%) | called by muse, mutect2, varscan2
- TACSTD2 | c.651G>C p.V217= | Silent (SNP) | VAF 99/542 reads (18%) | called by muse, mutect2, varscan2
- TENM3 | c.7584C>A p.L2528= | Silent (SNP) | VAF 34/265 reads (13%) | called by muse, mutect2, varscan2
- TIE1 | c.1758C>T p.D586= | Silent (SNP) | VAF 41/144 reads (28%) | catalogued as rs201759080; called by muse, mutect2, varscan2
- TLR8 | c.294C>G p.P98= (on ENST00000218032 / NM_138636.5; = p.P116= on NM_016610.4) | Silent (SNP) | VAF 37/233 reads (16%) | called by muse, mutect2, varscan2
- TMEM132D | c.963G>T p.T321= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs777841853; called by mutect2, varscan2
- TMPRSS11E | c.219T>C p.S73= | Silent (SNP) | VAF 25/198 reads (13%) | called by muse, mutect2, varscan2
- TRBV20-1 | c.105C>A p.I35= | Silent (SNP) | VAF 19/160 reads (12%) | called by muse, mutect2, varscan2
- TRIM21 | c.916C>A p.R306= | Silent (SNP) | VAF 9/68 reads (13%) | called by muse, varscan2
- TRPM6 | c.858G>T p.V286= | Silent (SNP) | VAF 109/459 reads (24%) | catalogued as rs527533154; called by muse, mutect2, varscan2
- TUBGCP2 | c.2181A>T p.T727= | Silent (SNP) | VAF 59/215 reads (27%) | called by muse, mutect2, varscan2
- UGT1A7 | c.507C>A p.A169= | Silent (SNP) | VAF 56/387 reads (14%) | called by muse, mutect2, varscan2
- UNC13A | c.252C>A p.T84= | Silent (SNP) | VAF 65/299 reads (22%) | called by muse, mutect2, varscan2
- VGLL1 | c.579C>A p.G193= | Silent (SNP) | VAF 62/170 reads (36%) | catalogued as COSV65703316; called by muse, mutect2, varscan2
- VPS13D | c.3147G>T p.V1049= | Silent (SNP) | VAF 31/173 reads (18%) | called by muse, mutect2, varscan2
- VWF | c.5142C>A p.A1714= | Silent (SNP) | VAF 124/641 reads (19%) | called by muse, mutect2, varscan2
- ZEB2 | c.1731A>T p.I577= | Silent (SNP) | VAF 18/222 reads (8%) | called by muse, mutect2
- ZNF229 | c.1818G>T p.G606= | Silent (SNP) | VAF 34/297 reads (11%) | called by muse, mutect2, varscan2
- ZNF229 | c.1647C>T p.C549= | Silent (SNP) | VAF 23/268 reads (9%) | catalogued as rs376063242; called by muse, mutect2
- ZNF230 | c.711G>T p.A237= | Silent (SNP) | VAF 72/702 reads (10%) | catalogued as COSV71273395; called by muse, mutect2, varscan2
- ZNF736 | c.294G>T p.V98= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV61907921, COSV61909045; called by muse, mutect2
- ABCC8 | c.3867+49C>A | Intron (SNP) | VAF 58/304 reads (19%) | catalogued as COSV56846445; called by muse, mutect2, varscan2
- ACBD7 | c.-19C>A | 5'UTR (SNP) | VAF 23/155 reads (15%) | catalogued as rs755735755; called by muse, mutect2, varscan2
- ADAM33 | c.905+31G>T | Intron (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- ATP7A | c.-21-8921G>T | Intron (SNP) | VAF 52/221 reads (24%) | called by muse, mutect2, varscan2
- ATP9B | chr18:79069382 G>T | 5'Flank (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- B4GALNT4 | c.*4C>T | 3'UTR (SNP) | VAF 12/67 reads (18%) | catalogued as rs529841698, COSV57323351; called by muse, varscan2
- CCDC88C | c.4441+13G>T | Intron (SNP) | VAF 25/212 reads (12%) | called by muse, mutect2, varscan2
- CICP4 | chr20:64287733 del C | 3'Flank (DEL) | VAF 53/210 reads (25%) | called by mutect2, pindel, varscan2
- CLK2P1 | n.689G>T | RNA (SNP) | VAF 56/636 reads (9%) | called by muse, mutect2
- CRIM1 | chr2:36552172 T>A | 3'Flank (SNP) | VAF 65/350 reads (19%) | called by muse, mutect2, varscan2
- CSNK1E | c.*20A>T | 3'UTR (SNP) | VAF 53/189 reads (28%) | called by muse, mutect2, varscan2
- CUL2 | c.-22-2749C>T | Intron (SNP) | VAF 19/170 reads (11%) | called by muse, mutect2, varscan2
- DPP9 | c.2092-139G>T | Intron (SNP) | VAF 28/132 reads (21%) | catalogued as rs1166947708; called by muse, mutect2, varscan2
- DTNB | c.1575+13C>G | Intron (SNP) | VAF 23/226 reads (10%) | called by muse, mutect2
- DZANK1 | chr20:18381192 C>G | 3'Flank (SNP) | VAF 62/429 reads (14%) | called by muse, mutect2, varscan2
- ELOB | c.4-38G>T | Intron (SNP) | VAF 22/77 reads (29%) | catalogued as rs766827848; called by muse, mutect2, varscan2
- FRMPD4 | c.*26A>G | 3'UTR (SNP) | VAF 20/111 reads (18%) | called by muse, mutect2, varscan2
- GABRG2 | c.259+33T>C | Intron (SNP) | VAF 23/250 reads (9%) | catalogued as rs749427741; called by muse, mutect2
- GCNT2 | c.925+26839C>T | Intron (SNP) | VAF 22/155 reads (14%) | called by muse, mutect2, varscan2
- GCNT2 | c.925+27037G>T | Intron (SNP) | VAF 35/150 reads (23%) | called by muse, mutect2, varscan2
- GRIK2 | c.2563-2526G>T | Intron (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- GUSBP1 | chr5:21459533 G>T | 5'Flank (SNP) | VAF 39/223 reads (17%) | called by muse, mutect2, varscan2
- GVINP1 | n.5704del | RNA (DEL) | VAF 14/119 reads (12%) | called by mutect2, pindel, varscan2
- HIPK1 | chr1:113929509 C>A | 5'Flank (SNP) | VAF 27/260 reads (10%) | called by muse, mutect2, varscan2
- HMCN1 | c.*25A>C | 3'UTR (SNP) | VAF 43/236 reads (18%) | called by muse, mutect2, varscan2
- HYDIN | c.3042+63T>A | Intron (SNP) | VAF 48/162 reads (30%) | called by muse, varscan2
- IGLV8OR8-1 | n.212G>T | RNA (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2, varscan2
- IL20RB | c.89-91A>T | Intron (SNP) | VAF 12/98 reads (12%) | called by muse, mutect2, varscan2
- ISCA1P1 | n.235C>G | RNA (SNP) | VAF 16/210 reads (8%) | called by muse, mutect2
- ITGAD | c.858+17C>A | Intron (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2, varscan2
- KCNK10 | c.-1G>C | 5'UTR (SNP) | VAF 87/280 reads (31%) | called by muse, mutect2, varscan2
- L2HGDH | chr14:50237698 C>A | 3'Flank (SNP) | VAF 10/83 reads (12%) | catalogued as COSV99910649; called by muse, mutect2, varscan2
- LACTB2 | c.286+842G>A | Intron (SNP) | VAF 19/141 reads (13%) | called by muse, mutect2, varscan2
- LINC01100 | n.148A>C | RNA (SNP) | VAF 33/245 reads (13%) | called by muse, mutect2, varscan2
- LINC01387 | n.432A>G | RNA (SNP) | VAF 28/116 reads (24%) | called by muse, mutect2, varscan2
- LINC02873 | n.360T>G | RNA (SNP) | VAF 14/67 reads (21%) | called by muse, varscan2
- LMBRD2 | c.*19G>T | 3'UTR (SNP) | VAF 40/134 reads (30%) | called by muse, mutect2, varscan2
- LTN1 | chr21:28992909 C>A | 5'Flank (SNP) | VAF 37/151 reads (25%) | catalogued as rs1028710528, COSV57478588; called by muse, mutect2, varscan2
- MMP19 | c.895+32G>A | Intron (SNP) | VAF 37/259 reads (14%) | called by muse, mutect2, varscan2
- MUC2 | chr11:1099376 C>T | 3'Flank (SNP) | VAF 22/202 reads (11%) | called by muse, varscan2
- MYO1F | c.636+59T>A | Intron (SNP) | VAF 68/212 reads (32%) | called by muse, mutect2, varscan2
- NANS | c.-36G>A | 5'UTR (SNP) | VAF 44/365 reads (12%) | called by muse, mutect2, varscan2
- NBPF11 | c.-549+2432G>A | Intron (SNP) | VAF 78/672 reads (12%) | catalogued as rs1205013541; called by muse, mutect2, varscan2
- NCDN | chr1:35557784 C>A | 5'Flank (SNP) | VAF 53/192 reads (28%) | called by muse, mutect2, varscan2
- NLGN4X | c.*33C>A | 3'UTR (SNP) | VAF 34/124 reads (27%) | called by muse, mutect2, varscan2
- NPFFR2 | c.299+36762A>G | Intron (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- NXF5 | n.533A>T | RNA (SNP) | VAF 109/334 reads (33%) | called by muse, mutect2, varscan2
- PLA2R1 | c.-21C>A | 5'UTR (SNP) | VAF 25/163 reads (15%) | called by muse, varscan2
- RASGRF2 | c.1390+352A>G | Intron (SNP) | VAF 24/174 reads (14%) | called by muse, mutect2, varscan2
- RHCG | c.975+22C>A | Intron (SNP) | VAF 23/78 reads (29%) | called by muse, mutect2, varscan2
- RNY4P30 | chr13:49891440 G>T | 5'Flank (SNP) | VAF 68/324 reads (21%) | called by muse, mutect2, varscan2
- SERPINB13 | c.473-157G>A | Intron (SNP) | VAF 54/274 reads (20%) | catalogued as rs754326375; called by muse, mutect2, varscan2
- SHLD1 | c.-5+6307A>T | Intron (SNP) | VAF 20/113 reads (18%) | called by muse, mutect2, varscan2
- SNORD115-20 | n.58G>T | RNA (SNP) | VAF 93/453 reads (21%) | catalogued as rs775127352; called by muse, mutect2, varscan2
- SNORD115-26 | n.76G>A | RNA (SNP) | VAF 125/461 reads (27%) | called by muse, mutect2, varscan2
- SNORD116-17 | chr15:25088329 G>T | 3'Flank (SNP) | VAF 30/132 reads (23%) | called by muse, varscan2
- SPANXN4 | chrX:143034592 G>T | 3'Flank (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
- SSPOP | n.14563C>A | RNA (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- SSX9P | n.115T>C | RNA (SNP) | VAF 43/160 reads (27%) | called by muse, mutect2, varscan2
- STAB2 | c.2086-25G>A | Intron (SNP) | VAF 25/123 reads (20%) | called by muse, mutect2, varscan2
- TEX45 | c.1207+154C>T | Intron (SNP) | VAF 36/148 reads (24%) | called by muse, varscan2
- TTN | c.10361-5133A>T | Intron (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- TXNDC8 | c.255+2195C>T | Intron (SNP) | VAF 38/183 reads (21%) | catalogued as rs1254082147; called by muse, mutect2, varscan2
- UNC5D | c.*2605G>T | 3'UTR (SNP) | VAF 21/65 reads (32%) | called by muse, mutect2, varscan2
- VHL | c.-18G>T | 5'UTR (SNP) | VAF 20/95 reads (21%) | called by muse, mutect2, varscan2
- VWA5B1 | c.710-108G>T | Intron (SNP) | VAF 20/105 reads (19%) | called by muse, mutect2, varscan2
- ZBBX | c.1880-6402C>A | Intron (SNP) | VAF 13/127 reads (10%) | called by muse, mutect2, varscan2
- ZNF606 | c.88+175G>T | Intron (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- ZNF658B | n.1005A>T | RNA (SNP) | VAF 81/466 reads (17%) | called by muse, mutect2, varscan2
- ZNF720 | c.361+323G>T | Intron (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- ZNF99 | c.*958del | 3'UTR (DEL) | VAF 52/336 reads (15%) | catalogued as COSV68056831; called by mutect2, pindel, varscan2
- ZNF99 | c.*205G>T | 3'UTR (SNP) | VAF 52/187 reads (28%) | called by muse, mutect2, varscan2
